Somatic mutation profile of tumor specimen HCM-BROD-0834-C43-06A (aliquot HCM-BROD-0834-C43-06A-11D-A85K-36) from HCMI case HCM-BROD-0834-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.9 years (28,828 days).
Specimen HCM-BROD-0834-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31048572-5910-4da8-9a51-4420a9919dd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0834-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0834-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac76d87-96e1-430f-bc1d-ab355582b4f5

The open-access MAF lists 1,267 somatic variants for this specimen: 803 protein-altering or splice-affecting, 423 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 732, Silent 423, Nonsense Mutation 47, Intron 30, Splice Region 11, Splice Site 8, Frame Shift Del 4, RNA 3, 3'Flank 3, 5'UTR 2, 3'UTR 2, 5'Flank 1.

Variants (750 of 1,267; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 149/588 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1064793134, CM096919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LMBRD1 | c.1222C>T p.R408* (on ENST00000649011; = p.R386* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | catalogued as rs1380343985, COSV65296997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 82/310 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4811G>A p.W1604* (on ENST00000303395 / NM_001202435.3; = p.W1593* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 90/341 reads (26%) | catalogued as rs794726800, CM1511236, COSV57668685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55289954; called by muse, mutect2, varscan2
- ABCA5 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 55/191 reads (29%) | catalogued as rs372523620; called by muse, mutect2, varscan2
- ABCA5 | c.129A>T p.L43F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1052359; called by muse, varscan2
- ABCB5 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 109/315 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.386); catalogued as COSV51702673; called by muse, mutect2, varscan2
- ABCC6 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 153/484 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52741958; called by muse, mutect2, varscan2
- ABHD16A | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 115/516 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs780830489; called by muse, mutect2, varscan2
- ABL2 | c.1342C>T p.P448S (on ENST00000502732 / NM_007314.4; = p.P433S on NM_005158.5) | Missense Mutation (SNP) | VAF 105/341 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866780586, COSV61018642; called by muse, mutect2, varscan2
- ABLIM3 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1197850966; called by muse, mutect2, varscan2
- ACE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371544905, COSV99327658; called by muse, mutect2, varscan2
- ACOD1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs1426756618; called by muse, varscan2
- ACTA2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs794728027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM18 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1228838970; called by muse, mutect2, varscan2
- ADAM18 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 120/408 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs865959777, COSV55845424; called by muse, mutect2, varscan2
- ADAM21 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99960599; called by muse, mutect2, varscan2
- ADAM29 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1222114163; called by muse, mutect2, varscan2
- ADAM7 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 104/354 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV51536126; called by muse, mutect2, varscan2
- ADAMTS13 | c.1437G>A p.G479= | Splice Region (SNP) | VAF 63/212 reads (30%) | catalogued as rs372953477, COSV63021506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51406470; called by muse, mutect2, varscan2
- ADAMTS18 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV51420155; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1447211714; called by muse, mutect2, varscan2
- ADCY4 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs777010278, COSV60252172; called by muse, mutect2, varscan2
- ADCY6 | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1226659148, COSV57168411; called by muse, mutect2, varscan2
- ADCY8 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 98/706 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as rs767845939; called by muse, mutect2, varscan2
- ADD2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.119); catalogued as COSV52454100; called by muse, mutect2, varscan2
- ADGRF5 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.735); catalogued as COSV51930822; called by muse, mutect2, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 116/452 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, mutect2, varscan2
- ADRA1D | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 150/507 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336684987, COSV65240762; called by muse, mutect2, varscan2
- AFF2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 196/310 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV53981943, COSV53983499; called by muse, mutect2, varscan2
- AGT | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 119/410 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs753775475; called by muse, mutect2, varscan2
- AHR | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 73/263 reads (28%) | catalogued as rs925497930; called by muse, mutect2, varscan2
- AICDA | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386378825; called by muse, mutect2, varscan2
- AKAP9 | c.8119G>A p.E2707K (on ENST00000359028; = p.E2683K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV62337878; called by muse, mutect2, varscan2
- AKAP9 | c.11066C>T p.S3689F (on ENST00000359028; = p.S3665F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62340221; called by muse, mutect2, varscan2
- AKR1C2 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1554771957; called by muse, mutect2, varscan2
- ALB | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV55735785; called by muse, mutect2, varscan2
- ALDOB | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV66397291; called by muse, mutect2, varscan2
- ALOX15 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756674821; called by muse, mutect2, varscan2
- ALPK2 | c.5236G>A p.E1746K | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100864934; called by muse, mutect2, varscan2
- AMY1C | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV100915196; called by muse, mutect2, varscan2
- AMY2A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs768370675; called by muse, mutect2, varscan2
- AMY2B | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 97/349 reads (28%) | catalogued as COSV100796442; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4808G>A p.S1603N | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.954); catalogued as rs780451476; called by muse, mutect2, varscan2
- ANKRD30B | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV62820400; called by muse, mutect2, varscan2
- ANKZF1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs376658598; called by muse, mutect2, varscan2
- ANO2 | c.2302C>T p.L768F (on ENST00000356134 / NM_001278597.3; = p.L772F on NM_001278596.3) | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765505051; called by muse, mutect2, varscan2
- AP4E1 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 72/243 reads (30%) | catalogued as COSV55917161; called by muse, mutect2, varscan2
- APOB | c.4522G>A p.D1508N | Missense Mutation (SNP) | VAF 97/360 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.112); catalogued as COSV51941751; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 106/369 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ATG4C | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100508614; called by muse, mutect2, varscan2
- ATP13A4 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 57/200 reads (29%) | catalogued as rs1472108737; called by muse, mutect2, varscan2
- ATXN1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 281/596 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs758093377, COSV55209499; called by muse, mutect2, varscan2
- AUTS2 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 164/500 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1384336956; called by muse, varscan2
- BAIAP3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100181502; called by muse, varscan2
- BAP1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV56236805, COSV99964448; called by muse, mutect2, varscan2
- BCAS3 | c.2435G>A p.R812Q (on ENST00000390652 / NM_001353144.2; = p.R797Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/337 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1396862585, COSV101174905; called by muse, mutect2, varscan2
- BCAT1 | c.675G>A p.G225= | Splice Region (SNP) | VAF 62/214 reads (29%) | catalogued as COSV53910615; called by muse, mutect2, varscan2
- BNIP5 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs750479175, COSV71325403; called by muse, mutect2, varscan2
- C12orf42 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs773446119, COSV59378762; called by muse, mutect2, varscan2
- C16orf54 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 149/471 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV61477125; called by muse, mutect2, varscan2
- C16orf90 | c.509G>A p.G170E (on ENST00000399645 / NM_001353385.2; = p.G161E on NM_001080524.2) | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as COSV101290966; called by muse, mutect2, varscan2
- C16orf92 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1489209519; called by muse, mutect2, varscan2
- CATSPERE | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1008364869; called by muse, mutect2, varscan2
- CBLL1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.658); catalogued as rs1207309123; called by muse, mutect2, varscan2
- CBLN3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 116/475 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs375714567; called by muse, mutect2, varscan2
- CCDC141 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55372398, COSV99836852; called by muse, mutect2, varscan2
- CCDC38 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780190657, COSV60183805; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CD163 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs867643659, COSV63135418; called by muse, mutect2, varscan2
- CD163 | c.1736-8C>T | Splice Region (SNP) | VAF 125/412 reads (30%) | catalogued as COSV63129888; called by muse, mutect2, varscan2
- CD163 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 104/356 reads (29%) | catalogued as rs750240390; called by muse, mutect2, varscan2
- CD163L1 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs1313926966; called by muse, mutect2, varscan2
- CDH9 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV50267939, COSV50312263; called by muse, mutect2, varscan2
- CDYL2 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 93/294 reads (32%) | catalogued as rs1455559785, COSV73647513; called by muse, mutect2, varscan2
- CELSR2 | c.6064C>T p.L2022F | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772338483; called by muse, mutect2, varscan2
- CFAP20DC | c.602G>A p.R201Q (on ENST00000482387 / NM_001351530.2; = p.R76Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs778956286, COSV55924982; called by muse, mutect2, varscan2
- CFAP47 | c.5099G>A p.W1700* | Nonsense Mutation (SNP) | VAF 32/62 reads (52%) | catalogued as COSV57973974; called by muse, mutect2, varscan2
- CFAP54 | c.4414C>T p.R1472C | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs1385646460, COSV61573182; called by muse, mutect2, varscan2
- CFAP54 | c.8686C>T p.R2896C | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs775459138; called by muse, mutect2, varscan2
- CHD8 | c.1972C>T p.P658S (on ENST00000646647 / NM_001170629.2; = p.P379S on NM_020920.4) | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs201662166, COSV67870298; called by muse, mutect2, varscan2
- CHST5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 151/504 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769120794, COSV60340043; called by muse, mutect2, varscan2
- CILP2 | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 111/442 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866357495; called by muse, mutect2, varscan2
- CLCA1 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.113); catalogued as COSV52329141; called by muse, mutect2, varscan2
- CLEC14A | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs113776316; called by muse, mutect2, varscan2
- CNTN4 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV61880694; called by muse, mutect2, varscan2
- CNTNAP3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs373851232, COSV99034462; called by muse, mutect2, varscan2
- COL11A1 | c.5069C>T p.S1690F | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62199099, COSV62200534; called by muse, mutect2, varscan2
- COL16A1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54711727; called by muse, mutect2, varscan2
- COL21A1 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55179809; called by muse, mutect2, varscan2
- COL6A5 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55213024; called by muse, mutect2, varscan2
- CORO7 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 115/409 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1163895377, COSV52029185; called by muse, mutect2, varscan2
- CPB1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs751218745; called by muse, mutect2, varscan2
- CPSF4 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 135/397 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52853780; called by muse, mutect2, varscan2
- CRYBG2 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1557715683; called by muse, mutect2, varscan2
- CSF3R | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100118120, COSV58969124; called by muse, varscan2
- CSF3R | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 86/296 reads (29%) | catalogued as COSV100117111; called by muse, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 109/661 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CSNKA2IP | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as rs1332778015; called by muse, mutect2, varscan2
- CUL7 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 153/479 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as CD1210391; called by muse, mutect2, varscan2
- CYFIP2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV59050054; called by muse, mutect2, varscan2
- CYP11A1 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.938); catalogued as rs867506250; called by muse, mutect2, varscan2
- CYP4A11 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 82/292 reads (28%) | catalogued as rs186780775; called by muse, mutect2, varscan2
- CYP4Z1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs762956296; called by muse, mutect2, varscan2
- DBR1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53430865; called by muse, mutect2, varscan2
- DCAF11 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58108520; called by muse, mutect2, varscan2
- DCC | c.2954C>A p.T985N | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59129228; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 58/268 reads (22%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCDC2B | c.851-1G>A p.X284_splice | Splice Site (SNP) | VAF 46/194 reads (24%) | catalogued as rs747754033; called by muse, mutect2
- DCLK2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56198740; called by muse, mutect2, varscan2
- DDAH1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.392); catalogued as rs763875537; called by muse, mutect2, varscan2
- DDX60L | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202002269; called by muse, mutect2, varscan2
- DDX60L | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761894325, COSV52716696; called by muse, mutect2, varscan2
- DGKI | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99932427; called by muse, mutect2, varscan2
- DGKK | c.1847G>A p.W616* | Nonsense Mutation (SNP) | VAF 66/103 reads (64%) | catalogued as COSV101053081, COSV65709104; called by muse, mutect2, varscan2
- DISP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53822416; called by muse, mutect2, varscan2
- DIXDC1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782795876, COSV101098127; called by muse, mutect2, varscan2
- DLEC1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 134/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57299582; called by muse, mutect2, varscan2
- DLG2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 94/333 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV101074484, COSV65860536; called by muse, mutect2, varscan2
- DMTN | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs146615047; called by muse, mutect2, varscan2
- DNAH10 | c.4384G>A p.E1462K (on ENST00000409039; = p.E1401K on NM_207437.3) | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.377); catalogued as COSV68992147; called by muse, mutect2, varscan2
- DNAH7 | c.6736C>T p.H2246Y | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1361587243, COSV56751994; called by muse, mutect2, varscan2
- DNAI3 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54000284; called by muse, mutect2, varscan2
- DNAJC10 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs775504249; called by muse, mutect2, varscan2
- DNER | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 134/472 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1189801764; called by muse, varscan2
- DOK6 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 47/134 reads (35%) | catalogued as rs1191838037, COSV66929858; called by muse, varscan2
- DPP10 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs147078556; called by muse, mutect2, varscan2
- DPP10 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1209458494, COSV59726814; called by muse, mutect2, varscan2
- DSCAM | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 123/388 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV68020915; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- ECD | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs1564664337; called by muse, mutect2, varscan2
- EMILIN2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV54426770; called by muse, mutect2, varscan2
- EPB41L2 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356999; called by muse, mutect2, varscan2
- EPHA6 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 122/360 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761842720; called by muse, mutect2, varscan2
- EPS8L3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100719756; called by muse, mutect2, varscan2
- ERBB4 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV61482936; called by muse, mutect2, varscan2
- ERBB4 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.858); catalogued as COSV53522603, COSV53585586; called by muse, mutect2, varscan2
- ERICH3 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 133/439 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751032690, COSV58619044; called by muse, mutect2, varscan2
- ERVV-1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs774584851; called by muse, mutect2, varscan2
- ERVW-1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.389); catalogued as rs1335678481; called by muse, mutect2, varscan2
- EYA1 | c.981G>A p.W327* | Nonsense Mutation (SNP) | VAF 55/262 reads (21%) | catalogued as COSV58168918; called by muse, mutect2, varscan2
- F13A1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV53562948; called by muse, mutect2, varscan2
- F7 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs550074221, CM090305, COSV60645310; called by muse, mutect2, varscan2
- FAM83C | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 136/433 reads (31%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV65582138; called by muse, mutect2, varscan2
- FAT2 | c.10388C>T p.S3463L | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as rs758888520, COSV55817482; called by muse, mutect2, varscan2
- FAT3 | c.3259G>A p.G1087S | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1261815109, COSV53109800; called by muse, mutect2, varscan2
- FBN2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199733916; called by muse, mutect2, varscan2
- FBXO40 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 126/374 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57527958; called by muse, mutect2, varscan2
- FLNB | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308690935; called by muse, mutect2, varscan2
- FREM1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 590/850 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101085369; called by muse, mutect2, varscan2
- GALNT13 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 90/301 reads (30%) | catalogued as rs1018857509, COSV67217164; called by muse, mutect2, varscan2
- GIMAP6 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100188092; called by muse, mutect2, varscan2
- GJB2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 120/432 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs104894403, CM109516, CM990690, COSV101241478; called by muse, mutect2, varscan2
- GLDN | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091151; called by muse, mutect2, varscan2
- GPATCH8 | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005554315, COSV100132835; called by muse, mutect2, varscan2
- GPR50 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 149/268 reads (56%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.033); catalogued as rs765410234; called by muse, mutect2, varscan2
- GRIN2A | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.747); catalogued as rs375160358, COSV58030043; called by muse, mutect2, varscan2
- GRM3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64468191; called by muse, mutect2, varscan2
- GRM4 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as rs750684981, COSV65211964; called by muse, mutect2, varscan2
- GRM7 | c.2214G>A p.M738I | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63161836; called by muse, mutect2, varscan2
- GRM8 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 111/319 reads (35%) | catalogued as rs1371651940; called by muse, mutect2, varscan2
- GRXCR1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV67670833; called by muse, mutect2, varscan2
- GYS2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1230733508; called by muse, mutect2, varscan2
- GZMB | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs969918445; called by muse, mutect2, varscan2
- HCN1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502899; called by muse, mutect2, varscan2
- HDAC1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 70/257 reads (27%) | catalogued as COSV61482340; called by muse, mutect2, varscan2
- HEPACAM2 | c.1007C>T p.S336F (on ENST00000394468 / NM_001039372.4; = p.S324F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV59060154; called by muse, mutect2, varscan2
- HFM1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54037359; called by muse, mutect2, varscan2
- HIVEP2 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs754278327, COSV50031237; called by muse, mutect2, varscan2
- HLCS | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs368743397; called by muse, mutect2, varscan2
- HYDIN | c.11830C>T p.R3944W | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1353096518, COSV66638801; called by muse, mutect2, varscan2
- ICE2 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55030727; called by muse, mutect2, varscan2
- IL36RN | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100697301, COSV61010445; called by muse, mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- IL7R | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as COSV57407340; called by muse, mutect2, varscan2
- INF2 | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 127/456 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs376315431; called by muse, mutect2, varscan2
- IQGAP2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs766715473, COSV57172166; called by muse, mutect2, varscan2
- IRF2BPL | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 134/433 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as rs369742014; called by muse, mutect2, varscan2
- ITGA3 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV99144008; called by muse, mutect2, varscan2
- IVL | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.351); catalogued as COSV100908099, COSV64216367; called by muse, mutect2, varscan2
- JAK3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1323968278; called by muse, mutect2, varscan2
- JRKL | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1391241792; called by muse, mutect2, varscan2
- JUP | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1321508670; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 214/351 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KCNIP4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752727409, COSV54842738; called by muse, mutect2, varscan2
- KCNQ3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 213/363 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66475740; called by muse, mutect2, varscan2
- KDM3A | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100461039; called by muse, mutect2, varscan2
- KDR | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780764266, COSV55760145, COSV55776827; called by muse, mutect2, varscan2
- KIF11 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs776614086, COSV53270028; called by muse, mutect2, varscan2
- KLK10 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 126/445 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs761167574; called by muse, mutect2, varscan2
- KLRD1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs781608711, COSV60273338, COSV60274015; called by muse, mutect2, varscan2
- KMT2B | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 142/525 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs773749210; called by muse, mutect2, varscan2
- KRT1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99078880; called by muse, mutect2, varscan2
- KRT84 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 135/372 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs747946695, COSV57770506; called by muse, mutect2, varscan2
- LDHAL6B | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 80/275 reads (29%) | catalogued as COSV55686597; called by muse, mutect2, varscan2
- LEPR | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV60748527; called by muse, mutect2, varscan2
- LGR4 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369900849; called by muse, mutect2, varscan2
- LGR6 | c.2549C>T p.P850L (on ENST00000367278 / NM_001017403.1; = p.P798L on NM_021636.3) | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV55166852; called by muse, mutect2, varscan2
- LILRB1 | c.199C>T p.L67F (on ENST00000427581; = p.L31F on NM_006669.6) | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs777936405, COSV61118496; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, mutect2, varscan2
- LPAR3 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV65453746; called by muse, mutect2, varscan2
- LRRC37A3 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 151/523 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV58534301, COSV58535602; called by muse, mutect2, varscan2
- LRRN4 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 120/419 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV101125425, COSV66645711; called by muse, mutect2, varscan2
- LSM14A | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 146/543 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs376476220, COSV70885139; called by muse, mutect2, varscan2
- LTK | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 147/486 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1424711608; called by muse, mutect2, varscan2
- MAGEC3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV74217459; called by muse, mutect2, varscan2
- MARCO | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs771963608, COSV59056016; called by muse, mutect2, varscan2
- MARCO | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.488); catalogued as COSV59052545; called by muse, mutect2, varscan2
- MDGA2 | c.2398C>T p.R800C (on ENST00000399232 / NM_001113498.2; = p.R502C on NM_182830.4) | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776310493, COSV62078486; called by muse, mutect2, varscan2
- MECOM | c.1567C>T p.P523S (on ENST00000468789 / NM_001105078.4; = p.P711S on NM_004991.4) | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV52959454; called by muse, mutect2, varscan2
- MECOM | c.515C>T p.S172L (on ENST00000468789 / NM_001105078.4; = p.S360L on NM_004991.4) | Missense Mutation (SNP) | VAF 89/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748747672, COSV52959668; called by muse, mutect2, varscan2
- MGAM2 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV101522985; called by muse, mutect2, varscan2
- MMP24 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV55770209; called by muse, mutect2, varscan2
- MMRN2 | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 140/439 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1357673791; called by muse, mutect2, varscan2
- MNDA | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1373560853; called by muse, mutect2, varscan2
- MTFR1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200858272, COSV50951197; called by muse, mutect2, varscan2
- MTNR1A | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56155582; called by muse, mutect2, varscan2
- MUC16 | c.27706G>A p.E9236K | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.069); catalogued as rs763596704; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- MUC16 | c.18184G>A p.E6062K | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.192); catalogued as rs892618039; called by muse, mutect2, varscan2
- MUC16 | c.10097C>T p.S3366F | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV67488011; called by muse, mutect2, varscan2
- MUC16 | c.7888C>T p.P2630S | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67476439; called by muse, mutect2, varscan2
- MUC16 | c.5513C>T p.A1838V | Missense Mutation (SNP) | VAF 98/380 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752594278; called by muse, mutect2, varscan2
- MYBBP1A | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs763901169; called by muse, mutect2, varscan2
- MYH11 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100259940; called by muse, mutect2, varscan2
- MYH15 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs750652915; called by muse, mutect2, varscan2
- MYL7 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs763245152; called by muse, mutect2, varscan2
- MYOM3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs745583615, COSV100292700; called by muse, mutect2, varscan2
- NAA11 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs868363838, COSV54514672; called by muse, mutect2, varscan2
- NBL1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV57029948; called by muse, mutect2, varscan2
- NCF4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs900312893, COSV99957156; called by muse, mutect2, varscan2
- NCKAP5 | c.3209C>T p.P1070L | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1415935134; called by muse, mutect2, varscan2
- NCOR2 | c.3147G>A p.W1049* | Nonsense Mutation (SNP) | VAF 155/523 reads (30%) | catalogued as COSV62298184; called by muse, mutect2, varscan2
- NDNF | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 118/380 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs772379451, COSV65634725; called by muse, mutect2, varscan2
- NECTIN3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs780559368, COSV60549749; called by muse, mutect2, varscan2
- NEXMIF | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 184/298 reads (62%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs767020320, COSV50069769; called by muse, mutect2, varscan2
- NEXMIF | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 130/214 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867424090, COSV50023304; called by muse, mutect2, varscan2
- NGDN | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1352006194; called by muse, mutect2, varscan2
- NLRP2 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.274); catalogued as rs1467652508; called by muse, mutect2, varscan2
- NLRP8 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.593); catalogued as rs142211286; called by muse, mutect2, varscan2
- NLRP8 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.271); catalogued as COSV52593443; called by muse, mutect2, varscan2
- NLRP9 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs773656654, COSV60462226; called by muse, mutect2, varscan2
- NPAS4 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.11); catalogued as COSV60651833; called by muse, mutect2, varscan2
- NRXN1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 137/496 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1312769037, COSV101280653; called by muse, mutect2, varscan2
- NUP160 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 90/253 reads (36%) | catalogued as COSV101021557; called by muse, mutect2, varscan2
- OCIAD1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1469980557; called by muse, mutect2, varscan2
- OPRD1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs780286580, COSV52382830; called by muse, mutect2, varscan2
- OPRL1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 150/478 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs772654648; called by muse, mutect2, varscan2
- OPRPN | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 113/373 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV68192656; called by muse, mutect2, varscan2
- OR10G7 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 153/359 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1253874078, COSV57866816; called by muse, mutect2, varscan2
- OR10G9 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs768083203, COSV66686101; called by muse, mutect2, varscan2
- OR10G9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV66686529; called by muse, mutect2, varscan2
- OR10J3 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs919949948; called by muse, mutect2, varscan2
- OR13C4 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs75737900; called by muse, mutect2, varscan2
- OR14A2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1356882880; called by muse, mutect2
- OR1F1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV58960347; called by muse, mutect2, varscan2
- OR1S2 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1324141028; called by muse, mutect2, varscan2
- OR2A2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68871596, COSV68871682; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2J3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 300/613 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs754215512, COSV65849020, COSV65849371; called by muse, mutect2, varscan2
- OR2T12 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs267598501, COSV58777909; called by muse, mutect2, varscan2
- OR2T35 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1386382144, COSV100442226; called by muse, mutect2, varscan2
- OR4K13 | c.812T>A p.L271H | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867962405; called by muse, mutect2, varscan2
- OR4N2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV60050111; called by muse, mutect2, varscan2
- OR4Q2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs983631004, COSV73406224; called by muse, mutect2, varscan2
- OR51A7 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs778988096, COSV100834717, COSV100834731; called by muse, mutect2, varscan2
- OR52E8 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781170349, COSV66205287; called by muse, mutect2, varscan2
- OR52I2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 117/446 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100443007; called by muse, mutect2, varscan2
- OR56A1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV57362472; called by muse, mutect2, varscan2
- OR56A4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs749332994; called by muse, mutect2
- OR5F1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 97/345 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV99558538; called by muse, mutect2, varscan2
- OR5H14 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV71194162; called by muse, mutect2, varscan2
- OR5H6 | c.611C>T p.S204F (on ENST00000642105; = p.S188F on NM_001005479.2) | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67351044; called by muse, mutect2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6C2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV59515501; called by muse, mutect2, varscan2
- OR6C4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV67793117; called by muse, mutect2, varscan2
- OR6F1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs866322456, COSV57469416; called by muse, mutect2, varscan2
- OR8H3 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs547287374, COSV57909356; called by muse, mutect2, varscan2
- OR8J1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV57318071; called by muse, mutect2, varscan2
- OSMR | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 72/241 reads (30%) | catalogued as rs199844167; called by muse, varscan2
- OTUD7B | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.46); catalogued as rs782297708; called by muse, mutect2, varscan2
- PABPC4L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs868469335, COSV69928983; called by muse, mutect2, varscan2
- PADI6 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs369382323; called by muse, mutect2, varscan2
- PAK5 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760772824, COSV62026820; called by muse, mutect2, varscan2
- PAK5 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV62030621; called by muse, mutect2, varscan2
- PALB2 | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs876659160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 110/402 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as COSV62783896; called by muse, mutect2, varscan2
- PASK | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 125/445 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs753967050; called by muse, mutect2, varscan2
- PBX1 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs761944828; called by muse, mutect2, varscan2
- PCDH15 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1051206153, COSV57256966, COSV57278999, COSV57411195; called by muse, mutect2, varscan2
- PCDH15 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57409812; called by muse, mutect2, varscan2
- PCDHA10 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs140022509, COSV56500580; called by muse, mutect2, varscan2
- PCDHA11 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as rs1554164197, COSV56488954, COSV56544731; called by muse, mutect2, varscan2
- PCDHA3 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 124/517 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs149543626; called by muse, mutect2, varscan2
- PCDHB15 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51031199; called by muse, mutect2, varscan2
- PCDHB4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 196/640 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782064797, COSV52028091, COSV99521960; called by muse, mutect2, varscan2
- PCDHB7 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 118/1390 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV50760573; called by muse, mutect2
- PCDHB8 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 197/1943 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV99177251; called by muse, mutect2, varscan2
- PCDHGA9 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.014); catalogued as COSV53972957; called by muse, mutect2, varscan2
- PCED1B | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71395453; called by muse, varscan2
- PCK1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs757690926; called by muse, mutect2
- PCLO | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779695259, COSV61653523; called by muse, mutect2, varscan2
- PHACTR2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766664422, COSV99992576; called by muse, mutect2, varscan2
- PHF20L1 | c.931-1G>A p.X311_splice | Splice Site (SNP) | VAF 52/373 reads (14%) | catalogued as COSV99620664; called by muse, mutect2, varscan2
- PKD1L1 | c.5420G>A p.R1807Q | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771122484; called by muse, mutect2, varscan2
- PLAGL2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 113/398 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs1341397214, COSV55789344; called by muse, mutect2, varscan2
- PLCH2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs753992333, COSV53951068; called by muse, mutect2, varscan2
- PLCZ1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 81/283 reads (29%) | catalogued as rs745955620, COSV56854741; called by muse, mutect2, varscan2
- PLPPR1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 124/387 reads (32%) | catalogued as COSV66457472; called by muse, mutect2, varscan2
- PLS1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61833525; called by muse, mutect2, varscan2
- PLXDC1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59554333; called by muse, mutect2, varscan2
- PLXNC1 | c.2113A>T p.K705* | Nonsense Mutation (SNP) | VAF 63/207 reads (30%) | catalogued as COSV51583617; called by muse, mutect2, varscan2
- PMFBP1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52829998; called by muse, mutect2, varscan2
- POLRMT | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 158/531 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs756790270; called by muse, mutect2, varscan2
- PPP4R4 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58557843; called by muse, mutect2, varscan2
- PRDM13 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.037); catalogued as rs1176630459; called by muse, mutect2, varscan2
- PRDM13 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.071); catalogued as rs1361020011; called by muse, mutect2, varscan2
- PRDM9 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs754142725, COSV57009588, COSV57012020; called by muse, mutect2, varscan2
- PROKR2 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 105/355 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs754872933; called by muse, mutect2, varscan2
- PRPF40B | c.1441C>T p.R481W (on ENST00000380281; = p.R475W on NM_012272.3) | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764686125, COSV56059152; called by muse, mutect2, varscan2
- PRRC2C | c.6890C>T p.S2297L (on ENST00000367742; = p.S2295L on NM_015172.4) | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58902730; called by muse, mutect2, varscan2
- PSG2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV61545145; called by muse, mutect2, varscan2
- PSG5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV61654589; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PSME3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as rs751193290, COSV53198717; called by muse, mutect2, varscan2
- PTCHD3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71256336; called by muse, mutect2, varscan2
- PTGIS | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773626394; called by muse, mutect2, varscan2
- PTPRD | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV61939357, COSV61957177; called by muse, mutect2, varscan2
- RABGAP1L | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV52290841; called by muse, mutect2, varscan2
- RAD21 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 268/428 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1337189031, COSV52056655; called by muse, mutect2, varscan2
- RASGRF2 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54126640; called by muse, mutect2, varscan2
- RAX2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 151/421 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.274); catalogued as rs370757303, COSV100349520; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RBMXL2 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV60979835; called by muse, mutect2, varscan2
- RELN | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV58991841; called by muse, mutect2, varscan2
- REXO1 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV50076132; called by muse, varscan2
- RGPD3 | c.3773C>T p.A1258V | Missense Mutation (SNP) | VAF 137/456 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58748035; called by muse, mutect2, varscan2
- RIN1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs137954374; called by muse, mutect2, varscan2
- RNF6 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1315955619, COSV60417908; called by muse, mutect2, varscan2
- RPL28 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 102/349 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as rs1320951324; called by muse, mutect2, varscan2
- RRAS2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV56330154; called by muse, mutect2, varscan2
- RTF1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67479083; called by muse, mutect2, varscan2
- RXFP2 | c.1002G>A p.L334= | Splice Region (SNP) | VAF 58/212 reads (27%) | catalogued as rs200224877, COSV53634179; called by muse, mutect2, varscan2
- RYR1 | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as rs1322440459, COSV100616015; called by muse, mutect2, varscan2
- RYR3 | c.4722C>G p.S1574R | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs1185351098, COSV101212473; called by muse, mutect2, varscan2
- SACS | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 111/354 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV66533644; called by muse, mutect2, varscan2
- SALL1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs867169108, COSV51761481; called by muse, mutect2, varscan2
- SAPCD1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 193/464 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as rs1234866850, COSV100991938; called by muse, mutect2, varscan2
- SCN10A | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs267599796, COSV71860696; called by muse, varscan2
- SCN10A | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV101479444; called by muse, mutect2
- SCN11A | c.3607A>T p.K1203* | Nonsense Mutation (SNP) | VAF 81/330 reads (25%) | catalogued as rs1553633785; called by muse, mutect2, varscan2
- SENP7 | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288003232, COSV100052721; called by muse, mutect2, varscan2
- SERPINB13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs376580897; called by muse, mutect2, varscan2
- SERPINB4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs140805883; called by muse, mutect2, varscan2
- SERPINB4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100345349; called by muse, mutect2, varscan2
- SETX | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs141996565; called by muse, mutect2, varscan2
- SIGLEC11 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.53); catalogued as rs544419480; called by muse, mutect2, varscan2
- SIGLEC12 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs150618212, COSV52464629; called by muse, mutect2, varscan2
- SIGLEC5 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1207503947; called by muse, mutect2, varscan2
- SLC17A4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 175/382 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757729766, COSV64957509; called by muse, mutect2, varscan2
- SLC25A24 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 159/520 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs866607066; called by muse, mutect2, varscan2
- SLC44A5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.216); catalogued as COSV63759539, COSV63760252; called by muse, mutect2, varscan2
- SLC5A8 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as rs778188770, COSV73311323; called by muse, mutect2
- SMG8 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 115/414 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs970762538; called by muse, mutect2, varscan2
- SMG9 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs775948640, COSV54215466; called by muse, mutect2, varscan2
- SP140 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs765460715, COSV59448176; called by muse, mutect2, varscan2
- SPA17 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187798202, COSV57031802, COSV57032417, COSV57032607; called by muse, mutect2, varscan2
- SPAG17 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV60463682; called by muse, mutect2, varscan2
- SPATA31D1 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 111/400 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.499); catalogued as COSV61193066, COSV61201208; called by muse, mutect2, varscan2
- SPATS2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 81/270 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773366687, COSV100423462; called by muse, mutect2, varscan2
- SPDYE6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 74/853 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs1554562299, COSV59504871; called by muse, mutect2
- SPHKAP | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60897672; called by muse, varscan2
- SPIDR | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761132270; called by muse, mutect2, varscan2
- SPTA1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV63753714; called by muse, mutect2, varscan2
- SRRM4 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57422964; called by muse, mutect2, varscan2
- SSTR1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 146/472 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs749916089, COSV57457993; called by muse, varscan2
- ST3GAL2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 116/405 reads (29%) | PolyPhen probably damaging (0.997); catalogued as COSV61595613; called by muse, mutect2, varscan2
- ST8SIA5 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 75/318 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100164518; called by muse, mutect2, varscan2
- ST8SIA6 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs759600604; called by muse, mutect2, varscan2
- STARD9 | c.9566C>T p.S3189F | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV51909462; called by muse, mutect2, varscan2
- STK4 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs371236375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 109/361 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs776148882, COSV54803377; called by muse, mutect2, varscan2
- SUFU | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs758001170; called by muse, mutect2, varscan2
- SYNE2 | c.4688C>T p.S1563L | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs748713876, COSV59941406; called by muse, mutect2, varscan2
- SYT10 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267603446; called by muse, mutect2, varscan2
- SYT17 | c.36T>C p.G12= | Splice Region (SNP) | VAF 33/110 reads (30%) | catalogued as rs930752613; called by muse, mutect2, varscan2
- TACC2 | c.5356C>T p.P1786S | Missense Mutation (SNP) | VAF 137/412 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs371867918; called by muse, mutect2, varscan2
- TBC1D8B | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 109/209 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778624354; called by muse, mutect2, varscan2
- TCFL5 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 91/294 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.829); catalogued as rs201056573, COSV53895417; called by muse, mutect2, varscan2
- TDRD15 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1470550466; called by muse, mutect2, varscan2
- TEK | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs771578973, COSV66228520; called by muse, mutect2, varscan2
- TENM4 | c.7222G>A p.D2408N | Missense Mutation (SNP) | VAF 118/371 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV53608601, COSV53656348; called by muse, mutect2, varscan2
- TENM4 | c.1987A>C p.M663L | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99571397; called by muse, mutect2, varscan2
- TENT5C | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65616213; called by muse, mutect2, varscan2
- TF | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV53924691; called by muse, mutect2, varscan2
- TGFBI | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759370852, COSV59352077, COSV59354114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THEMIS | c.1585A>G p.R529G | Missense Mutation (SNP) | VAF 300/646 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs755543363; called by muse, mutect2, varscan2
- THOP1 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as rs1416001453; called by muse, mutect2, varscan2
- TINAG | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52516310; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TLN2 | c.6477G>A p.T2159= | Splice Region (SNP) | VAF 65/194 reads (34%) | catalogued as rs921439954; called by muse, mutect2, varscan2
- TLR4 | c.1687G>A p.E563K (on ENST00000355622 / NM_138554.5; = p.E523K on NM_003266.4) | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.058); catalogued as COSV62924263; called by muse, mutect2, varscan2
- TMEM156 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs149276693, COSV60745754; called by muse, mutect2, varscan2
- TNC | c.6552G>A p.M2184I | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60780968; called by muse, mutect2, varscan2
- TNNI3K | c.1178-1G>A p.X393_splice | Splice Site (SNP) | VAF 55/221 reads (25%) | catalogued as rs907936579; called by muse, mutect2, varscan2
- TOR4A | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 169/499 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1464273319; called by muse, mutect2, varscan2
- TPTE | c.1340C>T p.S447L (on ENST00000618007 / NM_199261.4; = p.S429L on NM_199259.4) | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs759301774; called by muse, mutect2
- TRANK1 | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1197024240, COSV57154401; called by muse, mutect2, varscan2
- TRAV4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs372255405; called by muse, mutect2, varscan2
- TRHDE | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs767303355, COSV53830705; called by muse, mutect2, varscan2
- TRIM64B | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 141/906 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs765075149; called by muse, mutect2, varscan2
- TRPM6 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62506789; called by muse, mutect2, varscan2
- TRPS1 | c.1810C>T p.P604S (on ENST00000220888 / NM_001330599.2; = p.P617S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/633 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs369619683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.95951C>T p.P31984L (on ENST00000591111; = p.P24560L on NM_003319.4) | Missense Mutation (SNP) | VAF 86/288 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV100631974; called by muse, mutect2, varscan2
- TTN | c.64631G>A p.R21544Q (on ENST00000591111; = p.R14120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 112/389 reads (29%) | PolyPhen probably damaging (0.996); catalogued as rs201448988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.57961G>A p.D19321N (on ENST00000591111; = p.D11897N on NM_003319.4) | Missense Mutation (SNP) | VAF 113/388 reads (29%) | PolyPhen benign (0.001); catalogued as COSV100595767; called by muse, mutect2, varscan2
- TTN | c.29854C>T p.P9952S (on ENST00000591111; = p.P9025S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | PolyPhen benign (0.001); catalogued as COSV59916012; called by muse, mutect2, varscan2
- TTN | c.26746G>A p.E8916K (on ENST00000591111; = p.E7989K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/319 reads (30%) | PolyPhen possibly damaging (0.54); catalogued as COSV59918127; called by muse, mutect2, varscan2
- TTN | c.13067G>A p.G4356E (on ENST00000591111; = p.G4310E on NM_003319.4) | Missense Mutation (SNP) | VAF 90/328 reads (27%) | catalogued as rs374361492; called by muse, mutect2, varscan2
- UGT1A3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs143192251; called by muse, mutect2, varscan2
- UGT2A1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54139153; called by muse, mutect2, varscan2
- UGT3A2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs868312654, COSV56930235; called by muse, mutect2, varscan2
- UHRF1BP1L | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54435893; called by muse, mutect2, varscan2
- USP29 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54140543; called by muse, mutect2, varscan2
- VPS41 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV59648355; called by muse, mutect2, varscan2
- WDR97 | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 90/571 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs756021357, COSV100075861; called by muse, mutect2, varscan2
- WDTC1 | c.1720C>T p.R574C (on ENST00000319394 / NM_001276252.2; = p.R573C on NM_015023.5) | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1359642167, COSV99070421; called by muse, mutect2, varscan2
- WFS1 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 125/424 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs371911218, CD993079; called by muse, mutect2, varscan2
- YBX3 | c.264C>T p.A88= | Splice Region (SNP) | VAF 58/212 reads (27%) | catalogued as rs765950938; called by muse, mutect2, varscan2
- ZC4H2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758832940, COSV62002567; called by muse, mutect2, varscan2
- ZIM2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99032385; called by muse, mutect2, varscan2
- ZNF335 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs754027485; called by muse, mutect2, varscan2
- ZNF34 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 65/480 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV58641336; called by muse, mutect2, varscan2
- ZNF385D | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55749688; called by muse, mutect2, varscan2
- ZNF420 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100421552; called by muse, mutect2, varscan2
- ZNF527 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV62230007; called by muse, mutect2, varscan2
- ZNF665 | c.1234C>T p.R412W (on ENST00000600412; = p.R477W on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as rs866466787, COSV67213198; called by muse, mutect2, varscan2
- ZNF701 | c.979C>T p.H327Y (on ENST00000301093; = p.H261Y on NM_018260.3) | Missense Mutation (SNP) | VAF 126/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1001823737; called by muse, mutect2
- ZNF717 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 74/657 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1045936818; called by muse, mutect2
- ZNF862 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 107/388 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); catalogued as COSV56224798; called by muse, mutect2, varscan2
- ZSCAN18 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 121/421 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV53738214; called by muse, varscan2
- ZSWIM2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV54579407; called by muse, mutect2, varscan2
- ABCA12 | c.4865C>T p.P1622L (on ENST00000272895 / NM_173076.3; = p.P1304L on NM_015657.3) | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ABCB5 | c.491A>C p.N164T | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACSM2B | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, varscan2
- ADAMTS20 | c.4192T>A p.C1398S | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL5 | c.1229G>A p.W410* | Nonsense Mutation (SNP) | VAF 125/457 reads (27%) | called by muse, mutect2, varscan2
- ADAR | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 107/395 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRB1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 169/1027 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRD2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADGRF4 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADGRG4 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 121/198 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADGRL2 | c.2690T>C p.F897S (on ENST00000370717 / NM_001366005.1; = p.F884S on NM_012302.4) | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADGRV1 | c.17522G>A p.R5841K | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AGBL1 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- AGBL1 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGRN | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- AGRN | c.4511C>T p.A1504V | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AGXT2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AHNAK | c.6265C>T p.P2089S | Missense Mutation (SNP) | VAF 106/477 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- AKAP10 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKRD18B | c.1983G>C p.L661F | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ANKRD26 | c.2750T>C p.L917S | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANKRD30A | c.967A>T p.K323* (on ENST00000611781; = p.K267* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 171/488 reads (35%) | called by muse, mutect2, varscan2
- ANKRD33 | c.626C>G p.S209W (on ENST00000340970 / NM_001304459.2; = p.S334W on NM_182608.4) | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ANO5 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- APLF | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- APOB | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARG1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP11A | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ARHGAP33 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ARMC4 | c.1269del p.S424Afs*35 | Frame Shift Del (DEL) | VAF 51/265 reads (19%) | called by pindel, varscan2
- ASAH2 | c.1416G>A p.G472= | Splice Region (SNP) | VAF 61/218 reads (28%) | called by muse, mutect2, varscan2
- ASXL2 | c.1649A>T p.N550I | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10D | c.4061G>A p.G1354E | Missense Mutation (SNP) | VAF 127/373 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1B3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2A3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP2B1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- BRAT1 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 115/431 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRF2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- C10orf120 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C11orf42 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 195/512 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C3 | c.3161C>T p.T1054I | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CALML5 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAMTA1 | c.3850C>T p.P1284S | Missense Mutation (SNP) | VAF 128/388 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN14 | c.1430T>A p.I477K | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.2076A>T p.K692N | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CCDC141 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC150 | c.1816C>A p.L606I | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CCDC180 | c.2419T>C p.F807L | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC88B | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CCT7 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163L1 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CDH23 | c.5929C>T p.P1977S | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CEP290 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CERT1 | c.1697G>A p.G566E (on ENST00000405807 / NM_001130105.1; = p.G438E on NM_005713.3) | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CERT1 | c.1262A>C p.N421T (on ENST00000405807 / NM_001130105.1; = p.N293T on NM_005713.3) | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CFAP46 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2
- CFAP54 | c.589A>T p.N197Y | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD6 | c.6382C>T p.P2128S | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST5 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 151/504 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- CHSY1 | c.1147T>G p.Y383D | Missense Mutation (SNP) | VAF 122/359 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLDN19 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CLSTN2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CMBL | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CNR1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CNTNAP3 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL14A1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 220/359 reads (61%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A1 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 105/398 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- CPSF4 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPSF7 | c.572C>T p.S191F (on ENST00000394888 / NM_001136040.4; = p.S234F on NM_024811.4) | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CRADD | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CRYBG3 | c.2509T>G p.S837A | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD1 | c.1747T>A p.F583I (on ENST00000520002; = p.F582I on NM_033225.6) | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CTAGE8 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 58/691 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.499); called by muse, varscan2
- CTTNBP2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CXCL12 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 71/282 reads (25%) | called by muse, mutect2, varscan2
- CXCR1 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 122/430 reads (28%) | called by muse, mutect2, varscan2
- CYP2C8 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYREN | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAB2IP | c.1080T>G p.C360W (on ENST00000408936; = p.C332W on NM_032552.3) | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCDC2C | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DDX17 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DLC1 | c.2272C>T p.P758S (on ENST00000276297 / NM_001348081.2; = p.P321S on NM_006094.5) | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, varscan2
- DLL4 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DNAH5 | c.8330C>T p.T2777I | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- DNAH6 | c.9264G>A p.W3088* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- DNAH7 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1G | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- EHBP1 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 84/278 reads (30%) | called by muse, mutect2, varscan2
- EIF4A1 | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELFN1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 191/620 reads (31%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EPC1 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPHA10 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ERVV-1 | c.1329G>A p.W443* | Nonsense Mutation (SNP) | VAF 88/460 reads (19%) | called by muse, mutect2, varscan2
- ESPN | c.3030G>A p.W1010* | Nonsense Mutation (SNP) | VAF 123/525 reads (23%) | called by muse, mutect2, varscan2
- ESPN | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 122/523 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FAM71B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 116/431 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 135/940 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.10633C>T p.P3545S | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO10 | c.446T>C p.L149S | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FCN3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FCRL5 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD5 | c.3265-1G>A p.X1089_splice | Splice Site (SNP) | VAF 78/268 reads (29%) | called by muse, mutect2, varscan2
- FLT1 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOS | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRAS1 | c.11494C>T p.P3832S | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FREM2 | c.7753G>A p.D2585N | Missense Mutation (SNP) | VAF 126/347 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- FUT9 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FYB2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- GAGE10 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GALNT13 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- GALNT16 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GLI2 | c.2453C>T p.S818F (on ENST00000361492 / NM_001374353.1; = p.S835F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/509 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLRX5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 132/459 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRAMD2A | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- GRAMD2A | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GRWD1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GSDMC | c.1452G>A p.W484* | Nonsense Mutation (SNP) | VAF 365/565 reads (65%) | called by muse, mutect2, varscan2
- GTF3C4 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 103/339 reads (30%) | called by muse, mutect2, varscan2
- H1-7 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 144/466 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HAS1 | c.705C>T p.V235= | Splice Region (SNP) | VAF 71/212 reads (33%) | called by muse, mutect2, varscan2
- HECTD4 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW2 | c.3529G>A p.G1177S | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HEPHL1 | c.2565G>A p.M855I | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.12187C>T p.P4063S | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HMMR | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HOMEZ | c.1105G>C p.A369P | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HOXA4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 164/579 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HPSE2 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HRH1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HSPA1L | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- HYDIN | c.14134C>T p.P4712S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT122 | c.3614C>T p.T1205I (on ENST00000348417 / NM_052989.3; = p.T1146I on NM_018262.4) | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFT52 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- IGHV3-16 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 142/471 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGSF1 | c.1538G>A p.W513* | Nonsense Mutation (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- IGSF21 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL18RAP | c.143T>A p.L48* | Nonsense Mutation (SNP) | VAF 94/307 reads (31%) | called by muse, mutect2, varscan2
- IL23R | c.826T>G p.Y276D | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IQCM | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, varscan2
- IQCN | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 137/461 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IRX4 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 125/430 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ITGA8 | c.1608A>G p.I536M | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ITK | c.1493T>G p.V498G | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITPR1 | c.2362C>T p.H788Y (on ENST00000354582; = p.H773Y on NM_002222.7) | Missense Mutation (SNP) | VAF 134/440 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.5422G>A p.V1808I (on ENST00000354582; = p.V1753I on NM_002222.7) | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IZUMO2 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- JAKMIP3 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- JCAD | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- KCNA4 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCND2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ12 | c.124T>C p.C42R | Missense Mutation (SNP) | VAF 113/743 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK10 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1217 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- KIAA1217 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- KIAA1217 | c.5381C>T p.S1794F | Missense Mutation (SNP) | VAF 131/419 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF4B | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KMT2C | c.4610C>T p.P1537L | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KRT6C | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- LACTBL1 | c.8C>T p.P3L (on ENST00000618559; = p.P32L on NM_001289974.2) | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LACTBL1 | c.7C>T p.P3S (on ENST00000618559; = p.P32S on NM_001289974.2) | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 87/387 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA2 | c.4189G>A p.G1397R | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR6 | c.677G>A p.G226E (on ENST00000367278 / NM_001017403.1; = p.G174E on NM_021636.3) | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LHCGR | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX5 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LIMCH1 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LPIN1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC8E | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRSAM1 | c.1111T>C p.S371P | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MAGEC1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 136/232 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, varscan2
- MALRD1 | c.2482C>T p.H828Y | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAPK8IP3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCOL | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAST3 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MCHR2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ME1 | c.418T>A p.W140R | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- MECOM | c.947C>T p.P316L (on ENST00000468789 / NM_001105078.4; = p.P504L on NM_004991.4) | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MGAM2 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MGAM2 | c.3653T>G p.L1218W | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP13 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMRN1 | c.2504G>A p.R835K | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MST1R | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR4 | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- MUC12 | c.15955G>A p.D5319N (on ENST00000379442; = p.D5176N on NM_001164462.1) | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.13601C>T p.S4534F | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MUC16 | c.13072C>T p.Q4358* | Nonsense Mutation (SNP) | VAF 78/274 reads (28%) | called by muse, mutect2, varscan2
- MUC17 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MUC4 | c.7316C>T p.S2439F | Missense Mutation (SNP) | VAF 142/1006 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- MYB | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.4770G>A p.M1590I | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOM2 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYRFL | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL2 | c.5495C>T p.A1832V | Missense Mutation (SNP) | VAF 93/324 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NCKAP1L | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.2717G>A p.S906N | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEFH | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEFM | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- NF2 | c.888_912del p.I296Mfs*5 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | called by mutect2, pindel, varscan2
- NIPAL3 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRC4 | c.1908G>A p.M636I | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NMT1 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NOTCH1 | c.2167A>G p.N723D | Missense Mutation (SNP) | VAF 111/380 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NPY5R | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NRROS | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYX | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 171/301 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- OAZ1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OPN5 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR14A2 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR1L3 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR2AP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 57/184 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4A5 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 113/369 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR4X1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 111/390 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR51I1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5D16 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 115/399 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OR7C2 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 63/238 reads (26%) | called by muse, mutect2, varscan2
- OR8D1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OVCH2 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 108/484 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PAK5 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA11 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHGA10 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCLO | c.7766C>T p.P2589L | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PCLO | c.5512C>T p.P1838S | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by muse, varscan2
- PCLO | c.4580G>A p.R1527K | Missense Mutation (SNP) | VAF 128/367 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PDE1C | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 121/377 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PDGFRB | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKFB1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 91/152 reads (60%) | PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PGLYRP4 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 60/237 reads (25%) | called by muse, mutect2, varscan2
- PIM3 | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 84/291 reads (29%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6865G>A p.D2289N | Missense Mutation (SNP) | VAF 268/436 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PLEKHO1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PLG | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLPPR5 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLXNC1 | c.5_6del p.E2Gfs*185 | Frame Shift Del (DEL) | VAF 60/249 reads (24%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPP2R3A | c.3379A>T p.N1127Y | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PPP4R3C | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PPP6R1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 51/214 reads (24%) | called by muse, mutect2, varscan2
- PRKCQ | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 81/236 reads (34%) | called by muse, mutect2, varscan2
- PROS1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRUNE2 | c.5150G>A p.W1717* | Nonsense Mutation (SNP) | VAF 100/340 reads (29%) | called by muse, mutect2
- PRUNE2 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PSG8 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUM1 | c.3196C>T p.R1066* | Nonsense Mutation (SNP) | VAF 92/312 reads (29%) | called by muse, mutect2, varscan2
- RAB19 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 103/417 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI14 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RFFL | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 110/433 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RFPL4A | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 63/766 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2
- RFPL4AL1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2
- RGPD4 | c.3908C>T p.S1303F | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RGPD4 | c.4733T>C p.L1578S | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RGS4 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 99/323 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHBDL3 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RIT1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2
- RIT1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); called by muse, mutect2
- RNF6 | c.1596C>G p.H532Q | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO4 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ROS1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RP1 | c.1124G>T p.S375I | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RPS27AP5 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RYR1 | c.5582A>C p.Q1861P | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SARM1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 167/530 reads (32%) | called by muse, mutect2, varscan2
- SCAI | c.206C>T p.S69F (on ENST00000336505 / NM_001144877.3; = p.S92F on NM_173690.5) | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCART1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 109/401 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SCN3A | c.5365G>A p.D1789N | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNM1 | c.589del p.R197Efs*14 | Frame Shift Del (DEL) | VAF 62/272 reads (23%) | called by mutect2, pindel, varscan2
- SEC31A | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SFSWAP | c.408G>T p.L136F | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SH3PXD2A | c.2584C>T p.P862S (on ENST00000369774 / NM_001365079.1; = p.P834S on NM_014631.2) | Missense Mutation (SNP) | VAF 147/460 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC9 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SINHCAF | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SLC16A14 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, varscan2
- SLC1A4 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SLC1A6 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SLC22A11 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC24A3 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC38A3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SLC39A11 | c.692G>A p.R231K (on ENST00000542342 / NM_001159770.2; = p.R224K on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC46A1 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 133/429 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SLC6A5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 172/514 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLCO2A1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMIM24 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SNCAIP | c.2240G>A p.S747N | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SOS1 | c.3192T>G p.S1064R | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SPAG17 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SPANXN3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 163/257 reads (63%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPARC | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPATA31A7 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by mutect2, varscan2
- SPECC1 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SPEM3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ST8SIA3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 71/252 reads (28%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STK33 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- STON2 | c.958C>T p.P320S (on ENST00000649389 / NM_001366849.2; = p.P263S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SULT6B1 | c.566G>A p.W189* (on ENST00000535679 / NM_001367551.1; = p.W151* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 53/235 reads (23%) | called by muse, mutect2, varscan2
- SYN2 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 106/333 reads (32%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SYNE2 | c.8866C>T p.Q2956* | Nonsense Mutation (SNP) | VAF 79/274 reads (29%) | called by muse, mutect2, varscan2
- TAB1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 126/474 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TC2N | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 107/333 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
517 further variants in this file (53 protein-altering or splice-affecting, 423 silent, 41 other) are not listed here.
